Somatic mutation profile of tumor specimen TCGA-NA-A4R0-01A (aliquot TCGA-NA-A4R0-01A-11D-A28R-08) from TCGA case TCGA-NA-A4R0, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Fundus uteri; FIGO stage: Stage IVB; Age at diagnosis: 80.6 years (29,449 days).
Specimen TCGA-NA-A4R0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05bdbc66-47ed-4359-b684-03961ae490f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NA-A4R0-10A (Blood Derived Normal), aliquot TCGA-NA-A4R0-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/684cad69-d5e3-4307-8518-186f0f7314d6

The open-access MAF lists 59 somatic variants for this specimen: 37 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 18, Frame Shift Del 2, Intron 2, 5'Flank 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 8/29 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CCN3 | c.167C>G p.A56G | Missense Mutation (SNP) | VAF 2/20 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.23); catalogued as COSV52383578; called by muse, mutect2
- CILP2 | c.1615C>G p.P539A | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV52281034; called by muse, mutect2, varscan2
- CLDN4 | c.41C>G p.A14G | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as COSV52894907; called by muse, mutect2
- COL4A6 | c.3780C>A p.D1260E | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); catalogued as rs372872699; called by muse, mutect2, varscan2
- CYP2F1 | c.799T>A p.C267S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV58528464; called by muse, mutect2, varscan2
- HUWE1 | c.10543C>A p.P3515T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1556924273; called by muse, mutect2, varscan2
- KIFC3 | c.1901C>G p.T634R | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs781965077; called by muse, mutect2, varscan2
- KRT76 | c.1826G>T p.G609V | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV100196125; called by muse, mutect2, varscan2
- MAGEA11 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 64/320 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.16); catalogued as COSV60755102; called by muse, varscan2
- PCDHA7 | c.371A>G p.K124R | Missense Mutation (SNP) | VAF 24/281 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); catalogued as rs61730624; called by muse, mutect2
- POM121L12 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.249); catalogued as rs1192466338, COSV68692621, COSV68693468; called by muse, mutect2, varscan2
- PYCR2 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs755339149, COSV59524954; called by muse, mutect2, varscan2
- PYGM | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759218298, COSV51220100; called by muse, mutect2
- RNF181 | c.7T>C p.S3P | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1413226234; called by muse, mutect2, varscan2
- SMAD4 | c.10_11del p.M4Vfs*9 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs1064796471; called by pindel, varscan2
- STK3 | c.1195A>G p.K399E | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs1210425693; called by muse, mutect2, varscan2
- TRPC6 | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs200661450, COSV60257673; called by muse, mutect2, varscan2
- ZFAT | c.3362G>A p.G1121D | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs760429363; called by muse, mutect2, varscan2
- ZNF383 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 72/131 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.397); catalogued as rs1451086355; called by muse, mutect2, varscan2
- ZNF462 | c.5744A>G p.N1915S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1301878098; called by muse, mutect2, varscan2
- C1orf116 | c.1351del p.A451Qfs*5 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- C1orf43 | c.316G>C p.A106P (on ENST00000368521 / NM_001297718.2; = p.A72P on NM_015449.4) | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- DCTN5 | c.49-1G>C p.X17_splice | Splice Site (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- FANCM | c.1798C>A p.Q600K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2
- GLCE | c.750G>C p.W250C | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HP1BP3 | c.444G>T p.Q148H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- KLB | c.328T>C p.W110R | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL13 | c.329T>C p.V110A | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO3A | c.2473C>A p.L825I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCDHGA6 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLA2R1 | c.4019G>T p.G1340V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); called by muse, mutect2
- PXDNL | c.3374G>T p.R1125M | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- RHOXF1 | c.24C>A p.D8E | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- TSPOAP1 | c.4192G>A p.G1398R | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UST | c.980C>A p.T327N | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ARFGEF2 | c.2529G>A p.K843= | Silent (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- COX15 | c.60C>T p.L20= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1292679422; called by muse, mutect2, varscan2
- FCRL3 | c.1017G>T p.L339= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV100942722; called by muse, mutect2, varscan2
- HAPLN1 | c.600C>T p.G200= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs369262984; called by muse, mutect2, varscan2
- HUWE1 | c.10155C>T p.C3385= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2
- LYPLA2 | c.387C>G p.L129= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- MARS1 | c.165C>T p.S55= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as rs540781909; called by muse, mutect2, varscan2
- NDN | c.600G>C p.V200= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV100086373; called by muse, mutect2, varscan2
- NEDD4 | c.18A>T p.R6= | Silent (SNP) | VAF 11/118 reads (9%) | catalogued as rs767047105; called by muse, mutect2
- NPAP1 | c.402G>A p.A134= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV61505707, COSV61509662, COSV61512243; called by muse, mutect2, varscan2
- PDIA4 | c.189A>G p.G63= | Silent (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- PXN | c.1128G>A p.T376= (on ENST00000228307 / NM_001080855.3; = p.T342= on NM_002859.4) | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs747813672; called by muse, mutect2, varscan2
- RSBN1L | c.870A>G p.Q290= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs1300633524; called by muse, mutect2, varscan2
- SCN10A | c.1140A>C p.V380= | Silent (SNP) | VAF 18/163 reads (11%) | called by muse, mutect2, varscan2
- TTC3 | c.4542G>A p.E1514= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- WNT7A | c.351C>T p.H117= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as rs777739773; called by muse, mutect2, varscan2
- WWC3 | c.696C>A p.V232= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV66509322; called by muse, mutect2, varscan2
- ZNF567 | c.528T>C p.T176= (on ENST00000536254 / NM_001322913.1; = p.T145= on NM_152603.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498742 A>T | 5'Flank (SNP) | VAF 16/188 reads (9%) | catalogued as rs1243708885; called by muse, mutect2
- GLI2 | c.1183-49C>A | Intron (SNP) | VAF 16/91 reads (18%) | called by muse, mutect2, varscan2
- NACA | c.71-2625A>G | Intron (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- NXF5 | n.1379T>A | RNA (SNP) | VAF 53/235 reads (23%) | called by muse, mutect2, varscan2
